Gene-level copy-number profile of tumor specimen C3N-01413-01 from CPTAC case C3N-01413, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 62.2 years (22,704 days).
Specimen C3N-01413-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6d84e1fc-73a2-4361-8c6c-175d6c6e3193.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01413-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/7bc9bfe5-8362-447b-9395-d5c496d17fc3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 4,323; copy number 2: 26,009; copy number 3: 12,815; copy number 4: 12,360; copy number 5: 1,708; copy number 6: 817; copy number 8: 362; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:63,703,065–63,762,824, 5 genes: AL591438.2, CDRT15P7, AL772155.1, AL772155.2, MYO5BP3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,454 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–164,357,364, 871 genes, copy number 5–6 (broad region; genes not listed).
- chr1:228,384,114–230,612,412, 72 genes, copy number 5 (broad region; genes not listed).
- chr5:98,025,965–98,995,013, 20 genes, copy number 5: AC008834.1, LINC01846, AC116347.1, PSME2P1, AC233964.1, KRT8P32, MRPS35P2, MTCO2P24, MTCO1P24, CTBP2P4, DDX18P4, RGMB, RGMB-AS1, AC008522.1, CSNK1A1P3, CHD1, RNU6-402P, LINC02062, Y_RNA, AC022121.1.
- chr5:99,948,295–102,726,598, 37 genes, copy number 5: CRLF3P2, EEF1A1P20, Y_RNA, MTCYBP22, MTND6P22, MTND5P10, MTND4P35, MTND4LP5, MTND3P19, MTCO3P22, MTATP6P2, MTCO2P22, MTCO1P22, GUSBP7, RNU6-1119P, AC113385.3, AC113385.2, AC113385.1, AC021086.1, FAM174A, AC027315.1, RN7SKP62, ST8SIA4, MIR548P, RN7SL802P, OR7H2P, AC117525.1, RNA5SP188, AC008948.1, SLCO4C1, RN7SKP68, SLCO6A1, AC094108.1, LINC00492, LINC00491, AC099487.1, AC099487.2.
- chr5:106,815,197–107,735,066, 6 genes, copy number 5: LINC01950, PSMC1P5, EFNA5, AC024587.2, AC024587.1, RN7SL782P.
- chr5:120,245,448–122,479,087, 28 genes, copy number 5 (within-gene range 3–5): AC008574.1, RNU6-718P, AC113418.1, PRR16, PRELID3BP8, RNU4-69P, AC114284.1, AC008565.1, AC113352.1, AC008568.1, AC010350.1, AC008568.2, RPL23AP44, AC106806.1, AC106806.2, FTMT, SRFBP1, LOX, AC010255.1, ZNF474, AC010255.2, ZNF474-AS1, AC113349.2, SNCAIP, AC113349.1, AC119150.1, AC119150.2, MGC32805.
- chr5:138,610,967–143,828,772, 213 genes, copy number 5 (broad region; genes not listed).
- chr5:147,180,204–149,432,835, 51 genes, copy number 5: STK32A-AS1, STK32A, DPYSL3, AC011373.1, JAKMIP2-AS1, JAKMIP2, AC011370.1, SPINK1, AC011352.2, SCGB3A2, C5orf46, AC011352.1, AC011352.3, EEF1GP2, SPINK5, AC011346.1, SPINK14, SPINK6, HMGN1P16, MARCOL, SPINK13, PGBD4P3, SPINK7, SPINK9, AC091948.1, FBXO38, Metazoa_SRP, AC114939.1, HTR4, AC008627.1, ADRB2, SH3TC2, AC116312.1, RNU6-732P, MIR584, SH3TC2-DT, RN7SKP145, ABLIM3, AC012613.1, AC012613.2, AFAP1L1, AC131025.3, GRPEL2, GRPEL2-AS1, PCYOX1L, IL17B, AC131025.1, CARMN, AC131025.2, MIR143, MIR145.
- chr5:163,709,210–165,241,756, 12 genes, copy number 6: AC116917.1, RNU6-168P, AC008432.1, LSM1P2, AC008662.1, AC008662.2, AC109466.1, LINC02143, AC008446.1, RNU6-209P, AC091973.1, LINC01938.
- chr5:169,552,449–172,283,764, 43 genes, copy number 5: RNU6-477P, SPDL1, DOCK2, AC008680.1, INSYN2B, MIR378E, FOXI1, KRT18P41, LINC01187, C5orf58, LCP2, LINC01366, AC034199.1, KCNIP1, KCNMB1, KCNIP1-OT1, AC008619.1, KCNIP1-AS1, AC008514.1, GABRP, RANBP17, RN7SL623P, AC008514.2, USP12P1, AC091980.2, TLX3, AC091980.1, RN7SL339P, RPSAP71, SNORA70J, RPL10P8, MIR3912, NPM1, FGF18, AC093246.1, AC011410.1, SMIM23, FBXW11, STK10, EFCAB9, UBTD2, AC024561.1, KLF3P1.
- chr7:62,275,361–63,700,441, 41 genes, copy number 5: AC128676.1, RNU6-417P, AC069285.2, AC069285.3, ZNF90P3, SAPCD2P4, SEPTIN14P1, AC069285.1, AC092001.1, PHKG1P1, AC006455.8, SEPTIN7P4, AC006455.7, ZNF733P, AC006455.1, ARAFP3, AC006455.6, AC006455.5, AC006455.2, AC006455.3, AC006455.4, VN1R31P, VN1R32P, AC073188.3, AC073188.4, AC073188.2, AC073188.1, AC073188.5, AC073188.6, SLC25A1P2, VN1R33P, ARAFP2, ZNF734P, AC006457.1, SEPTIN7P5, PHKG1P2, SLC29A4P2, TNRC18P2, MIR4283-2, AC006015.1, AC079355.1.
- chr14:18,333,726–40,390,547, 697 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr19:27,793,431–38,636,955, 363 genes, copy number 8–15 (within-gene range 3–15) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,323. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
